Somatic mutation profile of tumor specimen C3N-03440-01 (aliquot CPT0246210010) from CPTAC case C3N-03440, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 54.5 years (19,891 days).
Specimen C3N-03440-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92ea7a9b-b0bd-44b2-9cb2-f6daba799532.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03440-31 (Blood Derived Normal), aliquot CPT0246250002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/089b9916-b527-4128-b42d-1ad4f70cdf7b

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 4, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 21/445 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CFAP251 | c.1813C>T p.P605S | Missense Mutation (SNP) | VAF 28/794 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV99996097; called by muse, mutect2
- DOCK6 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 16/264 reads (6%) | catalogued as rs765129469, COSV53915772; called by muse, mutect2
- FAM107A | c.231C>A p.N77K | Missense Mutation (SNP) | VAF 35/756 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV62980884; called by muse, mutect2
- PIK3R5 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs765654812, COSV52651342; called by muse, mutect2
- PLXNB2 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 24/599 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV63780090, COSV63780141; called by muse, mutect2
- SOX1 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 34/572 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868256636, COSV58380697; called by muse, mutect2
- ZNF521 | c.3325G>A p.V1109I | Missense Mutation (SNP) | VAF 12/283 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1259251891, COSV64129625; called by muse, mutect2
- COL4A6 | c.4147G>T p.G1383C | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPHB4 | c.1694A>G p.K565R | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- KIAA1671 | c.5163G>A p.M1721I | Missense Mutation (SNP) | VAF 25/337 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- MAT1A | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 42/830 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.092); called by muse, mutect2
- NTRK2 | c.2142G>T p.M714I (on ENST00000323115 / NM_001369534.1; = p.M730I on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/698 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- OR6P1 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 39/834 reads (5%) | SIFT tolerated (0.99); PolyPhen benign (0.17); called by muse, mutect2
- PCLO | c.5036A>C p.K1679T | Missense Mutation (SNP) | VAF 15/360 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2
- TPR | c.418T>A p.Y140N | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- GRM6 | c.678C>T p.G226= | Silent (SNP) | VAF 38/672 reads (6%) | catalogued as rs376072998, COSV99179457; called by muse, mutect2
- KCNA5 | c.1449C>T p.Y483= | Silent (SNP) | VAF 30/560 reads (5%) | catalogued as rs766020985, COSV99364252; called by muse, mutect2
- KCNA5 | c.1545C>T p.I515= | Silent (SNP) | VAF 34/579 reads (6%) | catalogued as rs1429404337, COSV52904695; called by muse, mutect2
- MARCHF11 | c.669C>A p.A223= | Silent (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- KIR3DX1 | n.1199A>G | RNA (SNP) | VAF 20/546 reads (4%) | called by muse, mutect2
